Surgical pathology report (de-identified scan), TCGA case TCGA-DZ-6135, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DZ-6135-01A (Primary Tumor).

Surgical Pathology
REVISED REPORT (Revised information underlined)

TISSUE DESCRIPTION:

Tissue from the left kidney (partial nephrectomy, 3.76 grams, 2.2 x 2.0 x 1.9 cm).

DIAGNOSIS:

Kidney, left, partial nephrectomy: Grade 1 (of 4) renal cell carcinoma, papillary type, forms a 1.9 x 1.7 x 1.7 cm mass. The tumor is confined to the kidney. Coagulative tumor necrosis is absent. Sarcomatoid differentiation is absent. The surgical margins are negative for tumor (free by 0.2 cm).

AMENDMENTS: (

Revision Description:

Review of permanent sections reveals the tumor to be a grade 1 (of

4) renal cell carcinoma, papillary type.

....Original Diagnosis....

Kidney, left, partial nephrectomy: Grade 1 (of 4) renal cell

carcinoma, clear cell type, forms a 1.9 x 1.7 x 1.7 cm mass. The

tumor is confined to the kidney. Coagulative tumor necrosis is

absent. Sarcomatoid differentiation is absent. The surgical

margins are negative for tumor (free by 0.2 cm).

Source: NCI Genomic Data Commons file 9cb95a20-e904-4f71-bb18-488c843ecc98 (TCGA-DZ-6135.BE2D1634-A014-4225-B105-062E41E034CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).